Somatic mutation profile of tumor specimen TCGA-61-2110-01A (aliquot TCGA-61-2110-01A-01W-0722-08) from TCGA case TCGA-61-2110, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Age at diagnosis: 56.7 years (20,718 days).
Specimen TCGA-61-2110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68a6ade8-d708-42d0-8dbf-c9562fe93626.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2110-11A (Solid Tissue Normal), aliquot TCGA-61-2110-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42a5bd32-ba8b-49eb-b639-13e95415d3e9

The open-access MAF lists 48 somatic variants for this specimen: 44 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 35, Nonsense Mutation 7, Silent 4, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 17/33 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52666031, COSV52675881, COSV52731113, COSV52828604; called by muse, mutect2, varscan2
- ARHGAP10 | c.2126C>A p.S709* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV100331849; called by muse, mutect2, varscan2
- AWAT1 | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV65738165; called by muse, mutect2, varscan2
- C7 | c.2105G>A p.C702Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201976045; called by muse, mutect2, varscan2
- CNTN5 | c.1979C>A p.S660* | Nonsense Mutation (SNP) | VAF 35/306 reads (11%) | catalogued as COSV99682119; called by muse, mutect2, varscan2
- COL17A1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV62225295; called by muse, mutect2, varscan2
- DAB2 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100298429; called by muse, mutect2
- DMD | c.5114C>T p.S1705L | Missense Mutation (SNP) | VAF 55/313 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV100823290; called by muse, mutect2, varscan2
- FAM124B | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 53/87 reads (61%) | catalogued as COSV66271281; called by muse, mutect2, varscan2
- FAM47A | c.2137C>A p.P713T | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV100649881, COSV60494047; called by muse, mutect2, varscan2
- GAREM1 | c.2333C>A p.S778Y (on ENST00000269209 / NM_001242409.2; = p.S777Y on NM_022751.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99331504; called by mutect2, varscan2
- HECW1 | c.4342G>A p.V1448M | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs758044929, COSV67822052; called by muse, mutect2, varscan2
- HMCN1 | c.11383C>T p.R3795* | Nonsense Mutation (SNP) | VAF 234/509 reads (46%) | catalogued as rs150673369, COSV54878020; called by muse, mutect2, varscan2
- HSD17B11 | c.715C>T p.P239S | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64153920; called by muse, mutect2, varscan2
- IGSF22 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100080559; called by muse, mutect2
- KHNYN | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs979523567, COSV52158789; called by muse, mutect2, varscan2
- KIAA1217 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56812508; called by muse, mutect2, varscan2
- MON1A | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as rs370838633, COSV56559318; called by mutect2, varscan2
- MON2 | c.4736C>T p.S1579F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99743852; called by muse, mutect2
- MYBBP1A | c.1183G>C p.V395L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV54593739, COSV99626311; called by muse, mutect2, varscan2
- OBSCN | c.812G>A p.W271* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV52741244; called by muse, varscan2
- PATJ | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 36/774 reads (5%) | catalogued as COSV100335144; called by muse, mutect2
- PCDHA4 | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs782098483, COSV63538939; called by muse, mutect2, varscan2
- PLD5 | c.620C>T p.T207M (on ENST00000442594; = p.T145M on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs773800524, COSV59134030; called by muse, mutect2, varscan2
- PREX1 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs755273231, COSV64247908; called by muse, mutect2, varscan2
- RANBP2 | c.3379C>T p.R1127* | Nonsense Mutation (SNP) | VAF 7/155 reads (5%) | catalogued as COSV99311079; called by muse, mutect2
- RCSD1 | c.789G>T p.K263N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV63257872; called by muse, mutect2, varscan2
- SASH3 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1044927153, COSV63555643; called by muse, mutect2, varscan2
- SFXN3 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99827609; called by muse, mutect2
- SHROOM2 | c.3506C>T p.S1169L | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs775435312, COSV66604634; called by muse, mutect2, varscan2
- SLC26A3 | c.73C>A p.H25N | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV100385334, COSV60642774; called by muse, mutect2
- SPEG | c.6697dup p.Q2233Pfs*90 | Frame Shift Ins (INS) | VAF 6/14 reads (43%) | catalogued as rs752907815; called by mutect2, varscan2
- SUCNR1 | c.978A>T p.E326D | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.007); catalogued as COSV62911840; called by muse, mutect2, varscan2
- TBC1D4 | c.3257C>T p.P1086L | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66487669; called by muse, mutect2, varscan2
- TCHH | c.5118G>C p.E1706D | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as COSV100915557; called by muse, mutect2, varscan2
- TMEM131 | c.1954A>G p.T652A | Missense Mutation (SNP) | VAF 22/767 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99489807; called by muse, mutect2
- TTN | c.65318T>C p.V21773A (on ENST00000591111; = p.V14349A on NM_003319.4) | Missense Mutation (SNP) | VAF 44/240 reads (18%) | PolyPhen benign (0.003); catalogued as COSV100633631; called by muse, mutect2, varscan2
- WWC3 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.482); catalogued as COSV66501599; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/170 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF185 | c.1370C>A p.S457Y | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV59274183; called by muse, mutect2, varscan2
- ZNF407 | c.5524G>A p.E1842K | Missense Mutation (SNP) | VAF 71/105 reads (68%) | SIFT tolerated (0.79); PolyPhen benign (0.079); catalogued as COSV100227384; called by muse, mutect2, varscan2
- ZNF785 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1360951885, COSV67876166; called by muse, mutect2, varscan2
- C14orf93 | c.725del p.N242Mfs*35 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by mutect2, varscan2
- PLIN4 | c.2792C>A p.T931N (on ENST00000301286; = p.T946N on NM_001367868.2) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2
- ARMC4 | c.1554G>T p.L518= | Silent (SNP) | VAF 41/197 reads (21%) | catalogued as COSV59456418; called by muse, mutect2, varscan2
- CCDC141 | c.2406C>G p.L802= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as COSV99837621; called by muse, mutect2
- MYT1L | c.1962T>C p.Y654= | Silent (SNP) | VAF 88/275 reads (32%) | catalogued as rs527880727, COSV67708618; called by muse, mutect2, varscan2
- TEP1 | c.1704C>T p.N568= | Silent (SNP) | VAF 120/265 reads (45%) | catalogued as rs558347552, COSV52988156; called by muse, mutect2, varscan2
